Somatic mutation profile of tumor specimen MMRF_2006_1_BM_CD138pos (aliquot MMRF_2006_1_BM_CD138pos_T1_KHS5U_L08100) from MMRF case MMRF_2006, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.2 years (22,351 days).
Specimen MMRF_2006_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 213d1d73-457c-4e78-b3b0-dc33a1a86a78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2006_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2006_1_PB_Whole_C2_KHS5U_L08101; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32117ec6-835b-4579-a663-e5927242d6d9

The open-access MAF lists 107 somatic variants for this specimen: 35 protein-altering or splice-affecting, 12 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 31, Missense Mutation 26, Intron 18, Silent 12, 5'UTR 4, Splice Site 4, 3'Flank 3, 5'Flank 3, Splice Region 2, Nonsense Mutation 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTG1 | c.137G>C p.G46A | Missense Mutation (SNP) | VAF 138/309 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.048); catalogued as COSV100111939; called by muse, mutect2, varscan2
- ANK1 | c.4870G>A p.D1624N | Missense Mutation (SNP) | VAF 286/470 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.311); catalogued as rs768806998, COSV99224215; called by muse, mutect2, varscan2
- ARHGEF18 | c.1180G>T p.D394Y (on ENST00000359920 / NM_001130955.2; = p.D290Y on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV104409390, COSV60467369; called by muse, mutect2, varscan2
- ATP13A5 | c.1241dup p.Y415Lfs*72 | Frame Shift Ins (INS) | VAF 110/188 reads (59%) | catalogued as rs1372907768; called by mutect2, pindel, varscan2
- CSTL1 | c.115A>G p.K39E | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0.012); catalogued as COSV55679033; called by muse, mutect2
- DIAPH3 | c.2738-1G>T p.X913_splice (on ENST00000400324 / NM_001042517.2; = p.X650_splice on NM_030932.3) | Splice Site (SNP) | VAF 40/103 reads (39%) | catalogued as rs1173953170; called by muse, mutect2, varscan2
- DLL3 | c.1772T>C p.L591P | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1164056815, COSV52694505; called by muse, mutect2
- ELF3 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1398134258, COSV100668959, COSV62839131, COSV62839867; called by muse, mutect2, varscan2
- IGHV2-70 | c.169T>C p.W57R | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs749669763; called by muse, varscan2
- NPAS3 | c.782G>A p.R261H (on ENST00000356141 / NM_001164749.2; = p.R229H on NM_022123.3) | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs950848692, COSV60835482, COSV60855705; called by muse, mutect2, varscan2
- OTOGL | c.1253T>G p.L418R (on ENST00000547103; = p.L409R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV72007321; called by muse, mutect2
- SLCO2A1 | c.861+6G>A | Splice Region (SNP) | VAF 97/381 reads (25%) | catalogued as rs551618431; called by muse, mutect2, varscan2
- TARDBP | c.719C>G p.A240G | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53569786; called by muse, mutect2, varscan2
- ABCA12 | c.7763C>A p.S2588* (on ENST00000272895 / NM_173076.3; = p.S2270* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 35/66 reads (53%) | called by muse, mutect2, varscan2
- ADAMTS19 | c.3312G>A p.K1104= | Splice Region (SNP) | VAF 83/127 reads (65%) | called by muse, mutect2, varscan2
- ANTXR2 | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 15/325 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- ARID4A | c.908C>A p.P303H | Missense Mutation (SNP) | VAF 80/202 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- BHLHE40 | c.258+1G>A p.X86_splice | Splice Site (SNP) | VAF 186/289 reads (64%) | called by muse, mutect2, varscan2
- C6orf132 | c.2590C>G p.L864V | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CCNQ | c.637del p.A213Lfs*133 | Frame Shift Del (DEL) | VAF 43/60 reads (72%) | called by mutect2, pindel, varscan2
- CHD5 | c.13G>A p.V5M | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLCN1 | c.433+1G>T p.X145_splice | Splice Site (SNP) | VAF 6/120 reads (5%) | called by muse, mutect2
- EGF | c.2681G>A p.G894D | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- EGFLAM | c.719A>C p.E240A | Missense Mutation (SNP) | VAF 53/95 reads (56%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IGHV2-70D | c.205C>G p.L69V | Missense Mutation (SNP) | VAF 76/91 reads (84%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.516); called by muse, varscan2
- IGHV2-70D | c.76T>G p.S26A | Missense Mutation (SNP) | VAF 41/45 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- MAGED2 | c.1497T>G p.I499M | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- PKD2 | c.1954G>T p.A652S | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- RNASE11 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 101/207 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- SLITRK6 | c.2054C>A p.P685H | Missense Mutation (SNP) | VAF 40/214 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYNE1 | c.8746T>G p.C2916G (on ENST00000367255 / NM_182961.4; = p.C2923G on NM_033071.3) | Missense Mutation (SNP) | VAF 73/211 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TRIM5 | c.563T>C p.L188P | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- UNC80 | c.3634-2A>T p.X1212_splice | Splice Site (SNP) | VAF 73/185 reads (39%) | called by muse, mutect2, varscan2
- ZNF235 | c.1529C>G p.T510R | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ZNF865 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.12); called by muse, mutect2
- CDH23 | c.5631C>T p.D1877= | Silent (SNP) | VAF 77/171 reads (45%) | catalogued as rs754048516; called by muse, mutect2, varscan2
- CHEK1 | c.810G>A p.K270= | Silent (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- FAM98C | c.951C>G p.G317= | Silent (SNP) | VAF 38/94 reads (40%) | catalogued as rs752762275, COSV53038491; called by muse, mutect2, varscan2
- FOXN4 | c.504G>A p.G168= | Silent (SNP) | VAF 39/68 reads (57%) | called by muse, mutect2, varscan2
- ITPK1 | c.645C>A p.L215= | Silent (SNP) | VAF 50/94 reads (53%) | called by muse, mutect2, varscan2
- MYO16 | c.4038T>C p.I1346= | Silent (SNP) | VAF 100/199 reads (50%) | called by muse, mutect2, varscan2
- P4HA3 | c.852G>A p.E284= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as rs1211523560; called by muse, mutect2, varscan2
- SPHKAP | c.3666C>G p.G1222= | Silent (SNP) | VAF 37/101 reads (37%) | called by muse, mutect2, varscan2
- SYNGR3 | c.633G>A p.P211= | Silent (SNP) | VAF 49/166 reads (30%) | catalogued as COSV50192487, COSV50192519; called by muse, mutect2, varscan2
- TBX15 | c.1155C>A p.G385= (on ENST00000369429 / NM_001330677.2; = p.G279= on NM_152380.3) | Silent (SNP) | VAF 37/80 reads (46%) | called by muse, mutect2, varscan2
- USP1 | c.1368C>T p.I456= | Silent (SNP) | VAF 112/264 reads (42%) | called by muse, mutect2, varscan2
- VMP1 | c.1155C>T p.N385= | Silent (SNP) | VAF 52/105 reads (50%) | catalogued as rs947768996, COSV51864373; called by muse, mutect2, varscan2
- ABCC8 | c.4120-49C>G | Intron (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2
- AC004947.2 | chr7:26534269 G>C | 5'Flank (SNP) | VAF 73/109 reads (67%) | called by muse, mutect2, varscan2
- AC009039.1 | chr16:52073869 A>G | 5'Flank (SNP) | VAF 37/93 reads (40%) | called by muse, mutect2, varscan2
- ACTG1 | c.-47G>T | 5'UTR (SNP) | VAF 107/195 reads (55%) | catalogued as rs201009307, COSV59510976; called by muse, mutect2, varscan2
- ARID1B | c.1887+18C>G | Intron (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- ARL5A | c.*3054A>G | 3'UTR (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- BAGE2 | chr21:10452506 A>G | 5'Flank (SNP) | VAF 8/63 reads (13%) | catalogued as rs75112368; called by muse, mutect2, varscan2
- BBOF1 | c.*833T>C | 3'UTR (SNP) | VAF 56/56 reads (100%) | called by muse, mutect2, varscan2
- BUD23 | c.510+53A>G | Intron (SNP) | VAF 82/217 reads (38%) | called by muse, mutect2, varscan2
- CA3 | c.*541T>A | 3'UTR (SNP) | VAF 61/176 reads (35%) | called by muse, mutect2, varscan2
- CACNB4 | c.*1490T>A | 3'UTR (SNP) | VAF 7/104 reads (7%) | catalogued as rs1396555430, COSV52397389; called by muse, mutect2
- CDX2 | c.*1001T>A | 3'UTR (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- CHN2 | c.1235+244C>T | Intron (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- CHST1 | c.*12C>T | 3'UTR (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2, varscan2
- CYLC2 | c.*268A>C | 3'UTR (SNP) | VAF 28/74 reads (38%) | called by muse, mutect2, varscan2
- DGKB | c.2307+626A>G | Intron (SNP) | VAF 6/146 reads (4%) | called by muse, mutect2
- DOK3 | chr5:177502288 del TT | 3'Flank (DEL) | VAF 59/103 reads (57%) | called by mutect2, pindel, varscan2
- F2R | c.88+323C>A | Intron (SNP) | VAF 14/318 reads (4%) | called by muse, mutect2
- FSTL5 | c.*287T>G | 3'UTR (SNP) | VAF 60/111 reads (54%) | called by muse, mutect2, varscan2
- GPS1 | c.699+76C>T | Intron (SNP) | VAF 113/256 reads (44%) | catalogued as rs1386701732; called by muse, mutect2, varscan2
- KLF9 | c.*165A>T | 3'UTR (SNP) | VAF 76/213 reads (36%) | called by muse, varscan2
- LTB | c.162+137C>G | Intron (SNP) | VAF 34/90 reads (38%) | catalogued as rs186447095, COSV53001762; called by muse, mutect2, varscan2
- MAOA | c.*31T>G | 3'UTR (SNP) | VAF 157/160 reads (98%) | called by muse, mutect2, varscan2
- MCMDC2 | c.*2508T>C | 3'UTR (SNP) | VAF 129/197 reads (65%) | catalogued as rs866914577; called by muse, mutect2, varscan2
- MED17 | c.417+212T>G | Intron (SNP) | VAF 66/215 reads (31%) | called by muse, mutect2, varscan2
- MED20 | c.*77G>T | 3'UTR (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- MED6 | c.*253_*254del | 3'UTR (DEL) | VAF 18/30 reads (60%) | called by pindel, varscan2
- NCOR1 | c.*520A>G | 3'UTR (SNP) | VAF 63/123 reads (51%) | called by muse, mutect2, varscan2
- NIPA1 | c.*2835T>C | 3'UTR (SNP) | VAF 31/97 reads (32%) | called by muse, mutect2, varscan2
- NRBP2 | c.1317+48G>A | Intron (SNP) | VAF 39/117 reads (33%) | catalogued as rs782062839; called by muse, mutect2, varscan2
- NT5M | c.*414G>T | 3'UTR (SNP) | VAF 94/196 reads (48%) | catalogued as rs971979509; called by muse, mutect2, varscan2
- NTN1 | c.*632C>T | 3'UTR (SNP) | VAF 40/80 reads (50%) | called by muse, mutect2, varscan2
- NUDT16 | c.409-33G>T | Intron (SNP) | VAF 22/62 reads (35%) | catalogued as COSV100720820; called by muse, mutect2, varscan2
- PABPC5 | c.*1364T>G | 3'UTR (SNP) | VAF 33/33 reads (100%) | called by muse, mutect2, varscan2
- PAX5 | c.*7081A>C | 3'UTR (SNP) | VAF 81/131 reads (62%) | called by muse, mutect2, varscan2
- PBRM1 | chr3:52547814 T>C | 3'Flank (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- PCDHGA3 | c.2425-66450C>T | Intron (SNP) | VAF 3/47 reads (6%) | catalogued as rs946434728; called by muse, mutect2
- PKIB | c.-9+48G>A | Intron (SNP) | VAF 14/42 reads (33%) | called by mutect2, varscan2
- PNLIPRP1 | c.331-299T>C | Intron (SNP) | VAF 58/134 reads (43%) | catalogued as rs1354453160; called by muse, mutect2, varscan2
- PPP1R2 | c.*2310G>C | 3'UTR (SNP) | VAF 11/307 reads (4%) | called by muse, mutect2
- PPP3R1 | c.-391C>T | 5'UTR (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- PSPC1P1 | n.438G>A | RNA (SNP) | VAF 31/45 reads (69%) | called by muse, mutect2, varscan2
- PTPRT | c.*7459A>C | 3'UTR (SNP) | VAF 33/67 reads (49%) | called by muse, mutect2, varscan2
- PYGO1 | c.*4021A>T | 3'UTR (SNP) | VAF 107/158 reads (68%) | called by muse, mutect2, varscan2
- RAB3IL1 | c.*54G>C | 3'UTR (SNP) | VAF 46/135 reads (34%) | called by muse, mutect2, varscan2
- RIMS4 | c.*2156G>T | 3'UTR (SNP) | VAF 8/163 reads (5%) | called by muse, mutect2
- RN7SL484P | chr15:99792355 C>T | 3'Flank (SNP) | VAF 41/127 reads (32%) | catalogued as rs546446758; called by muse, mutect2, varscan2
- SEMA6A | c.*2880T>C | 3'UTR (SNP) | VAF 31/96 reads (32%) | catalogued as rs1255140420; called by muse, mutect2, varscan2
- SMARCA5 | c.*3691G>C | 3'UTR (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- SP3 | c.*815A>T | 3'UTR (SNP) | VAF 60/138 reads (43%) | called by muse, mutect2, varscan2
- ST18 | c.2363+42C>T | Intron (SNP) | VAF 77/270 reads (29%) | catalogued as rs771386035; called by muse, mutect2, varscan2
- TENM3 | c.*2408G>T | 3'UTR (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- TMEM252 | c.*667C>A | 3'UTR (SNP) | VAF 14/91 reads (15%) | called by muse, mutect2, varscan2
- TMEM267 | c.*980A>G | 3'UTR (SNP) | VAF 31/123 reads (25%) | called by muse, mutect2, varscan2
- TPCN2 | c.1539+93G>T | Intron (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- TPP1 | c.1076-20C>G | Intron (SNP) | VAF 5/96 reads (5%) | called by muse, mutect2
- TREM1 | c.-25C>T | 5'UTR (SNP) | VAF 329/456 reads (72%) | catalogued as rs762663199; called by muse, mutect2, varscan2
- TTC31 | c.546+92A>G | Intron (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- UBE2N | c.-30G>T | 5'UTR (SNP) | VAF 73/143 reads (51%) | called by muse, mutect2, varscan2
- UBE2W | c.*3115G>T | 3'UTR (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
